Somatic mutation profile of cancer-model specimen HCM-CSHL-0088-C25-85A (3D Organoid; aliquot HCM-CSHL-0088-C25-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0088-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 75.4 years (27,551 days).
Specimen HCM-CSHL-0088-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56c9d73d-d9da-497f-b425-43f92125b60f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0088-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0088-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cb6d815-232e-4e20-bbd0-83cb3996ccb6

The open-access MAF lists 58 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 12, Intron 4, 3'UTR 3, 5'UTR 3, RNA 3, Nonsense Mutation 2, Splice Site 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 145/316 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NR5A1 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 36/838 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886039769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- SLC22A5 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs386134223, CM033027, CM120316, COSV99809649; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 337/338 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BOC | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 193/374 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs759609900; called by muse, mutect2, varscan2
- CADPS2 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs761503610, COSV57358606; called by muse, mutect2, varscan2
- CDKN2A | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 415/417 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM035015, CM097978, COSV58696521; called by muse, mutect2, varscan2
- COPS7B | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 13/372 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as COSV62601661; called by muse, mutect2
- CPN2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 35/396 reads (9%) | catalogued as rs758477993; called by muse, mutect2
- DACT1 | c.1802T>C p.V601A | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs200318568; called by muse, mutect2, varscan2
- GRIA1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as rs1489199965, COSV99602523; called by muse, mutect2, varscan2
- POLR3E | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs779326078; called by muse, mutect2
- THEM6 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 327/607 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1554642439; called by muse, mutect2, varscan2
- TNS1 | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as rs540388747; called by muse, mutect2, varscan2
- AQP1 | c.367T>G p.S123A | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by mutect2, varscan2
- ARID1A | c.2988+2T>G p.X996_splice | Splice Site (SNP) | VAF 76/138 reads (55%) | called by muse, mutect2, varscan2
- CACNA1C | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD3E | c.419T>G p.I140S | Missense Mutation (SNP) | VAF 215/487 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CNOT1 | c.3542A>G p.K1181R | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTNND1 | c.1599C>A p.C533* | Nonsense Mutation (SNP) | VAF 44/65 reads (68%) | called by muse, varscan2
- DDX17 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 47/664 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.201); called by muse, mutect2
- FREM1 | c.3763G>C p.D1255H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2D | c.12888_12902del p.L4296_V4301delinsF | In Frame Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel
- LTB4R | c.455T>G p.V152G | Missense Mutation (SNP) | VAF 135/329 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- NPAS4 | c.1074C>A p.S358R | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PDCD11 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNASEL | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 130/250 reads (52%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SCEL | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX13C | c.950A>G p.K317R | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- WDTC1 | c.425C>A p.T142K | Missense Mutation (SNP) | VAF 129/234 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZBTB40 | c.1777A>C p.I593L | Missense Mutation (SNP) | VAF 256/559 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF729 | c.2939C>T p.T980I | Missense Mutation (SNP) | VAF 138/322 reads (43%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- AHNAK | c.12456C>T p.P4152= | Silent (SNP) | VAF 26/660 reads (4%) | called by muse, mutect2
- CDKN2A | c.282G>T p.L94= | Silent (SNP) | VAF 398/402 reads (99%) | called by muse, varscan2
- CFAP46 | c.3060C>T p.F1020= | Silent (SNP) | VAF 25/165 reads (15%) | catalogued as rs1410921002; called by muse, mutect2, varscan2
- EOMES | c.1383C>T p.S461= | Silent (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- FMNL1 | c.2526G>A p.L842= | Silent (SNP) | VAF 53/108 reads (49%) | called by muse, mutect2, varscan2
- GSX1 | c.147G>A p.A49= | Silent (SNP) | VAF 25/369 reads (7%) | called by muse, mutect2
- HELZ2 | c.3501C>T p.F1167= (on ENST00000467148 / NM_001037335.2; = p.F598= on NM_033405.3) | Silent (SNP) | VAF 27/394 reads (7%) | catalogued as rs376041753; called by muse, mutect2
- NHS | c.618G>A p.P206= | Silent (SNP) | VAF 64/269 reads (24%) | catalogued as rs200952266; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- SLC39A12 | c.612G>A p.T204= | Silent (SNP) | VAF 192/361 reads (53%) | catalogued as rs773815080, COSV66195481; called by muse, mutect2, varscan2
- TNFAIP2 | c.180G>A p.A60= | Silent (SNP) | VAF 27/262 reads (10%) | catalogued as COSV60693871; called by muse, mutect2
- TNFRSF6B | c.279C>T p.V93= | Silent (SNP) | VAF 48/512 reads (9%) | catalogued as rs373053031; called by muse, mutect2
- TROAP | c.1551G>A p.P517= | Silent (SNP) | VAF 21/266 reads (8%) | catalogued as rs748007426; called by muse, mutect2
- AC127029.3 | c.*24C>A | 3'UTR (SNP) | VAF 45/367 reads (12%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846084 C>T | 5'Flank (SNP) | VAF 18/94 reads (19%) | catalogued as rs764431964; called by muse, mutect2, varscan2
- AMT | c.1033+36C>T | Intron (SNP) | VAF 231/393 reads (59%) | called by muse, mutect2, varscan2
- BCAT1 | c.7-973G>A | Intron (SNP) | VAF 32/344 reads (9%) | called by muse, mutect2
- BTBD8 | c.833+74T>G | Intron (SNP) | VAF 27/51 reads (53%) | called by muse, mutect2, varscan2
- INPP5K | c.-10G>T | 5'UTR (SNP) | VAF 156/156 reads (100%) | called by muse, mutect2, varscan2
- LINC00922 | n.846C>T | RNA (SNP) | VAF 15/222 reads (7%) | catalogued as rs768945220; called by muse, mutect2
- MAGEA3 | c.-91C>T | 5'UTR (SNP) | VAF 249/529 reads (47%) | called by muse, mutect2, varscan2
- MAP2K6 | c.367-12A>G | Intron (SNP) | VAF 57/128 reads (45%) | called by muse, mutect2, varscan2
- MVB12A | c.*13_*31del | 3'UTR (DEL) | VAF 20/40 reads (50%) | called by mutect2, pindel
- NLRP3 | c.-36G>A | 5'UTR (SNP) | VAF 187/357 reads (52%) | catalogued as rs755242195; called by muse, mutect2, varscan2
- PKD1L2 | n.2718C>A | RNA (SNP) | VAF 18/251 reads (7%) | catalogued as rs542299761; called by muse, mutect2
- QSOX1 | c.*1359T>C | 3'UTR (SNP) | VAF 14/157 reads (9%) | called by muse, mutect2
- SNORD115-20 | n.1G>A | RNA (SNP) | VAF 165/365 reads (45%) | called by muse, mutect2, varscan2
